Somatic mutation profile of tumor specimen TCGA-BP-4992-01A (aliquot TCGA-BP-4992-01A-01D-1462-08) from TCGA case TCGA-BP-4992, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 66.9 years (24,438 days).
Specimen TCGA-BP-4992-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e7354cf-a064-41af-ac4f-9268c4938dfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4992-11A (Solid Tissue Normal), aliquot TCGA-BP-4992-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/800d2f9b-f271-4075-9003-3ce6bb48b366

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHEB | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 39/204 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519949, COSV51263142, COSV51264088; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5153T>G p.I1718S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV66071511; called by muse, mutect2, varscan2
- ACE | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.405); catalogued as COSV52027986; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV59481233; called by muse, mutect2, varscan2
- BNC1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61758411; called by muse, mutect2, varscan2
- BOD1L1 | c.3533C>G p.A1178G | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV50083380; called by muse, mutect2, varscan2
- BOD1L1 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV50084190; called by muse, mutect2, varscan2
- CDC16 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV52962309; called by muse, mutect2, varscan2
- CLUH | c.3187C>T p.Q1063* (on ENST00000435359; = p.Q1102* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV70930198; called by muse, mutect2, varscan2
- GLOD5 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57490149; called by muse, mutect2
- INPP5A | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV61253912; called by muse, varscan2
- KCNN1 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418671781, COSV55842722; called by muse, mutect2
- MMP25 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs778484081, COSV60681595; called by muse, mutect2, varscan2
- MTAP | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66478677; called by muse, mutect2, varscan2
- MYO1F | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs750553132, COSV57795167; called by muse, mutect2, varscan2
- MYOM3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58399875, COSV58402055; called by muse, mutect2, varscan2
- NOD2 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56055291; called by muse, varscan2
- PDIA6 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV55354277; called by muse, mutect2, varscan2
- PEAK1 | c.5044C>T p.P1682S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1343672586, COSV56944541; called by muse, mutect2, varscan2
- PLXNB2 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63784928; called by muse, mutect2
- PNKP | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV55591003; called by muse, mutect2, varscan2
- PROSER3 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV56555327; called by muse, mutect2, varscan2
- PRSS37 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV63340279; called by muse, mutect2, varscan2
- RETREG1 | c.1034G>T p.R345I (on ENST00000306320 / NM_001034850.2; = p.R204I on NM_019000.4) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV60452638; called by muse, mutect2, varscan2
- SLC13A3 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51724156; called by muse, mutect2, varscan2
- SMARCA4 | c.3557C>G p.A1186G | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60788639, COSV60811013; called by muse, mutect2, varscan2
- WAC | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61569704, COSV61570095; called by muse, mutect2, varscan2
- WASHC4 | c.2267A>C p.N756T | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59892734; called by muse, mutect2, varscan2
- ZNF407 | c.3206A>C p.K1069T | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55272788; called by muse, mutect2, varscan2
- ZNF473 | c.2575C>G p.R859G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54523352, COSV54525409; called by muse, mutect2, varscan2
- BTG1 | c.63dup p.I22Hfs*32 | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- ZNF827 | c.2018_2025del p.K673Tfs*5 | Frame Shift Del (DEL) | VAF 32/218 reads (15%) | called by mutect2, pindel, varscan2
- AQP12A | c.81C>A p.A27= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV61837850; called by muse, mutect2, varscan2
- C7orf25 | c.819G>A p.E273= | Silent (SNP) | VAF 67/261 reads (26%) | catalogued as rs1409445128, COSV63274433; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1440C>T p.F480= (on ENST00000439118 / NM_001008949.3; = p.F488= on NM_178495.6) | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as COSV63154943; called by muse, mutect2, varscan2
- MYL5 | c.303C>T p.A101= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs367674993; called by muse, mutect2
- PCDHA12 | c.1962C>T p.H654= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV56551810; called by muse, mutect2, varscan2
- RNF130 | c.1257T>C p.F419= | Silent (SNP) | VAF 60/257 reads (23%) | catalogued as COSV56154413; called by muse, mutect2, varscan2
- RNF165 | c.210G>A p.P70= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53975019; called by muse, mutect2
- SH3RF3 | c.1641G>T p.G547= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV58687997, COSV58696704; called by muse, mutect2, varscan2
- TAF1B | c.1128C>T p.F376= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as rs369161786, COSV55160477; called by muse, mutect2, varscan2
- FBLN1 | c.1698-9589G>A | Intron (SNP) | VAF 15/78 reads (19%) | catalogued as COSV53054787; called by muse, mutect2, varscan2
- MIR515-1 | n.49C>T | RNA (SNP) | VAF 15/100 reads (15%) | called by muse, varscan2
